Gene-level copy-number profile of tumor specimen TCGA-IG-A97I-01A from TCGA case TCGA-IG-A97I, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 58.2 years (21,271 days).
Specimen TCGA-IG-A97I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.a41c8467-377d-441d-9705-c49fb6bcbb0a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IG-A97I-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6fb68625-6807-488a-ab28-86570506362d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 8,500; copy number 2: 44,198; copy number 3: 5,617; copy number 4: 1,102; copy number 5: 176; copy number 6: 21; copy number 7: 124; copy number 9: 32; copy number 22: 12; copy number 24: 15; copy number 36: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IG-A97I-01A-11D-A386-01): tumor purity 0.63, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,898,423–141,208,376, 4 genes: LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.
- chr3:54,874,605–54,901,255, 1 gene: CACNA2D3-AS1.
- chr4:21,304,468–21,350,673, 1 gene: AC110296.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 389 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:5,990,927–6,784,843, 30 genes, copy number 9: KCNAB2, CHD5, AL031847.1, RPL22, RNF207-AS1, RNF207, ICMT, LINC00337, HES3, GPR153, ACOT7, AL031848.2, HES2, ESPN, MIR4252, AL031848.1, TNFRSF25, PLEKHG5, NOL9, RNU6-731P, AL591866.1, TAS1R1, ZBTB48, KLHL21, PHF13, THAP3, DNAJC11, LINC01672, AL591163.1, CAMTA1-DT.
- chr1:6,834,333–7,014,279, 2 genes, copy number 9: AL590128.1, AL512330.1.
- chr3:148,279,682–153,980,186, 115 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr3:175,369,540–181,867,154, 107 genes, copy number 5–7 (broad region; genes not listed).
- chr8:106,980,967–109,345,954, 25 genes, copy number 5: AP003789.1, AP000428.2, HMGB1P46, AP000428.1, ANGPT1, AC091010.1, PGAM1P13, AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2.
- chr8:135,234,131–138,914,041, 17 genes, copy number 5: LINC01591, AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P, LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1.
- chr11:55,466,771–55,812,476, 21 genes, copy number 6: OR4A13P, OR4A50P, OR4A21P, OR4C1P, OR4C14P, OR4C15, OR4C16, OR4C11, OR4P4, OR4S2, OR4C6, OR4V1P, OR4P1P, AP006437.1, OR5D2P, OR5D3P, OR5D17P, OR5D13, OR5D15P, OR5D14, OR5L1.
- chr11:67,991,100–70,436,584, 72 genes, copy number 5–36 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,081. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
